Somatic mutation profile of tumor specimen MMRF_2061_1_BM_CD138pos (aliquot MMRF_2061_1_BM_CD138pos_T1_KBS5U_L07207) from MMRF case MMRF_2061, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.4 years (27,163 days).
Specimen MMRF_2061_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2537472c-3730-4734-8637-898b62f969f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2061_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2061_1_PB_Whole_C2_KBS5U_L07208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2dd5e4f-2432-430d-8317-838920203c1d

The open-access MAF lists 213 somatic variants for this specimen: 88 protein-altering or splice-affecting, 32 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 48, Silent 32, Intron 22, 5'UTR 13, Nonsense Mutation 5, 5'Flank 4, RNA 3, 3'Flank 3, Splice Site 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPE | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs144716013, CM147400; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGF3 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 67/147 reads (46%) | catalogued as rs121917704, CM070117, COSV100490202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs143806721, COSV57839785; called by muse, mutect2, varscan2
- AR | c.2631C>A p.F877L | Missense Mutation (SNP) | VAF 134/222 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65953135, COSV65960450; called by muse, mutect2, varscan2
- ATAD5 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV58978707; called by muse, mutect2
- ATP10B | c.2789G>A p.R930K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780232585, COSV59165674; called by muse, mutect2, varscan2
- BRINP1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1473785, COSV56292284, COSV56310660; called by muse, mutect2, varscan2
- BRIP1 | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52006989; called by muse, mutect2, varscan2
- CDK15 | c.1283C>G p.P428R (on ENST00000652192 / NM_001366386.2; = p.P377R on NM_139158.2) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1351202760; called by muse, mutect2, varscan2
- CMKLR1 | c.724A>G p.T242A (on ENST00000312143 / NM_001142344.2; = p.T240A on NM_004072.3) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs936309837; called by muse, mutect2, varscan2
- DACT3 | c.1854C>A p.F618L | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56261623; called by muse, mutect2, varscan2
- DCSTAMP | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs760055630; called by muse, mutect2, varscan2
- DHRS13 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as rs774830836; called by muse, varscan2
- DTX1 | c.88T>A p.W30R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57502318; called by muse, varscan2
- IFIT1 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758970620; called by muse, mutect2, varscan2
- IGHV1-69 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs373835979; called by muse, mutect2, varscan2
- IGHV1-69 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs573757399; called by mutect2, varscan2
- IGHV2-70 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs372477786; called by muse, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375225384; called by muse, varscan2
- ITGB4 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1336118560; called by muse, mutect2, varscan2
- KIF27 | c.4120C>T p.R1374* | Nonsense Mutation (SNP) | VAF 13/153 reads (8%) | catalogued as rs369241220; called by muse, mutect2
- PAN2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780940788; called by muse, varscan2
- PCDHA4 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs782755918; called by muse, mutect2, varscan2
- PCSK5 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1196522326; called by muse, mutect2
- PCSK5 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs765807770, COSV65084154; called by muse, mutect2, varscan2
- PEG10 | c.574G>T p.A192S (on ENST00000482108 / NM_001040152.2; = p.A226S on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/240 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.734); catalogued as COSV71788042; called by muse, mutect2, varscan2
- PIPOX | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV60143660; called by muse, mutect2
- PLAA | c.2166A>T p.K722N | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1485708739; called by muse, mutect2
- PRR23C | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1212399708; called by muse, mutect2
- RAET1L | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1383115438, COSV99657767; called by muse, mutect2, varscan2
- RP1L1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200724846; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC32A1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV54146196; called by muse, mutect2, varscan2
- SP140 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs771219707, COSV104415539, COSV59446882; called by muse, mutect2, varscan2
- TET2 | c.3781C>T p.R1261C | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898441677, COSV54397005, COSV54424071, COSV99485797; called by muse, mutect2, varscan2
- TLN2 | c.4619A>G p.N1540S | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); catalogued as COSV60886787; called by muse, mutect2, varscan2
- TMCO4 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs764253154, COSV53870125; called by muse, mutect2, varscan2
- TOPBP1 | c.4377G>C p.Q1459H | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99604876; called by muse, mutect2
- TOPORS | c.3095del p.S1032Yfs*2 | Frame Shift Del (DEL) | VAF 25/250 reads (10%) | catalogued as COSV62117853; called by mutect2, pindel, varscan2
- UBQLN2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV100592772; called by muse, mutect2, varscan2
- UBR4 | c.5062G>A p.V1688M | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753527168, COSV64386588; called by muse, mutect2, varscan2
- WDR11 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV54786376; called by muse, mutect2
- ZNF324 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs749013727, COSV99543307; called by muse, mutect2
- ZNF536 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV62820152; called by muse, mutect2, varscan2
- ABI3BP | c.2021C>G p.A674G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC100868.1 | c.1603T>C p.F535L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ACACA | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- ADAM32 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALDH6A1 | c.1565C>G p.T522S | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- ASB7 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ATP2B2 | c.2558C>G p.A853G (on ENST00000352432; = p.A819G on NM_001683.5) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP8B3 | c.2530G>A p.V844M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2
- BAZ1B | c.4159C>T p.Q1387* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- CC2D2A | c.1707G>C p.Q569H | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CDH20 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ELF4 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FAM189A1 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FANCM | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.5742T>A p.S1914R | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FXR1 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GPR158 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXA6 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- JAG1 | c.1120+2T>G p.X374_splice | Splice Site (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- LEO1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LINGO1 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MAGEB6B | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 122/211 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MISP | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NRDE2 | c.442del p.R148Afs*11 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- PAPSS1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCF11 | c.4616T>C p.I1539T | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.3301T>G p.S1101A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- POLQ | c.5264C>T p.T1755I | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RFX6 | c.2222G>A p.S741N | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL22 | c.243-2A>G p.X81_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- SKOR1 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SLC44A2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2
- TBCCD1 | c.1589A>T p.Y530F | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2
- TENM1 | c.7422T>A p.T2474= | Splice Region (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- TMEM72 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TPGS1 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPRN | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRIM60 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TYMP | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, varscan2
- TYMP | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC5C | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VCP | c.328T>G p.Y110D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ZNF335 | c.1434_1436del p.E478del | In Frame Del (DEL) | VAF 63/139 reads (45%) | called by mutect2, pindel, varscan2
- ZNF569 | c.1892A>G p.E631G | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAS1 | c.438G>A p.P146= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs374609444; called by muse, mutect2, varscan2
- BEX1 | c.162C>T p.R54= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs374272158; called by muse, mutect2
- CHCHD5 | c.195C>T p.F65= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs370720308; called by muse, mutect2, varscan2
- CMA1 | c.258C>T p.D86= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs772646026; called by muse, mutect2
- CUX2 | c.2037C>T p.I679= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs745929765, COSV55624908; called by muse, mutect2, varscan2
- DHRS13 | c.690G>A p.V230= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- DNAH17 | c.12498C>T p.V4166= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as COSV53149375; called by muse, mutect2, varscan2
- FTMT | c.321C>A p.A107= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- FZD10 | c.972G>A p.S324= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- HNRNPD | c.153C>T p.T51= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs367953381; called by muse, varscan2
- KDM4B | c.1560C>T p.A520= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- MAGEL2 | c.2385G>A p.Q795= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- MPV17L | c.516C>T p.D172= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs746944644; called by muse, mutect2, varscan2
- NOL8 | c.1767G>A p.L589= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- NOMO1 | c.1491C>A p.A497= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- NPHP4 | c.3987C>T p.L1329= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1352217291; called by muse, mutect2, varscan2
- NPSR1 | c.342C>T p.F114= | Silent (SNP) | VAF 32/219 reads (15%) | catalogued as rs1230310356; called by muse, mutect2, varscan2
- OOEP | c.90G>A p.P30= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs748888992, COSV100949804; called by muse, mutect2, varscan2
- OR10A2 | c.597G>A p.L199= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs770612840; called by muse, mutect2, varscan2
- OSBPL3 | c.501C>T p.T167= | Silent (SNP) | VAF 53/203 reads (26%) | called by muse, mutect2, varscan2
- PIPOX | c.669G>A p.R223= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as rs901512873; called by muse, mutect2
- PKHD1L1 | c.10986T>C p.P3662= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1157045209, COSV101006737; called by muse, mutect2, varscan2
- PRKD1 | c.855G>A p.Q285= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as rs1271529947; called by muse, mutect2, varscan2
- RASA1 | c.306G>A p.V102= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- SEMA6D | c.1422T>C p.H474= | Silent (SNP) | VAF 37/309 reads (12%) | catalogued as rs147987261, COSV60376485; called by muse, mutect2, varscan2
- SH3KBP1 | c.864C>T p.I288= | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- STARD5 | c.225A>G p.L75= | Silent (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- TAS2R50 | c.241A>C p.R81= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- TYMP | c.1326G>A p.R442= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- TYMP | c.1242G>A p.P414= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1013301590; ClinVar: likely benign; called by muse, mutect2, varscan2
- TYMP | c.759G>A p.K253= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, varscan2
- AC020907.6 | c.-561C>T | 5'UTR (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- APBB1 | c.1503+53G>A | Intron (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- ATF4 | chr22:39520538 del G | 5'Flank (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- BAIAP3 | c.-60G>A | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- BMP6 | c.*1321G>C | 3'UTR (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- C17orf97 | c.*279G>A | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- C2orf88 | c.*1089T>C | 3'UTR (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- C5orf58 | chr5:170232710 C>G | 5'Flank (SNP) | VAF 12/126 reads (10%) | catalogued as rs1247151066; called by muse, mutect2
- CASP10 | c.1415+8425C>T | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- CCDC117 | c.*2523C>G | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- CHST10 | c.-104+490G>A | Intron (SNP) | VAF 55/124 reads (44%) | catalogued as rs973641433; called by muse, mutect2, varscan2
- CLCN4 | c.*1512T>A | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CPLX1 | c.*573T>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5889658 G>T | 5'Flank (SNP) | VAF 11/267 reads (4%) | called by muse, mutect2
- CTDSPL | c.*2094G>A | 3'UTR (SNP) | VAF 8/100 reads (8%) | catalogued as rs1157634053; called by muse, mutect2
- DNAL4 | c.153+188T>A | Intron (SNP) | VAF 19/83 reads (23%) | catalogued as rs1339004177; called by muse, mutect2, varscan2
- DOLK | c.-289G>C | 5'UTR (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- DPH3 | c.109-112T>C | Intron (SNP) | VAF 36/65 reads (55%) | catalogued as rs556311768; called by mutect2, varscan2
- EBF3 | chr10:129835862 C>T | 3'Flank (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- EIF2AK1 | c.*104G>C | 3'UTR (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- EPHA5 | c.*4514T>G | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- FAM220A | c.-43C>T | 5'UTR (SNP) | VAF 48/201 reads (24%) | catalogued as rs542967267, COSV57627732; called by muse, mutect2, varscan2
- FIGN | c.*1742T>G | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- FSTL5 | c.*906T>A | 3'UTR (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.*1564G>A | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- GALNT2 | c.*1915G>A | 3'UTR (SNP) | VAF 54/136 reads (40%) | catalogued as rs901059547; called by muse, mutect2, varscan2
- GLS | c.1650+2208A>T | Intron (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- GPCPD1 | c.*2329C>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- GRHL3 | c.-39G>A | 5'UTR (SNP) | VAF 40/254 reads (16%) | catalogued as rs747314561; called by muse, mutect2, varscan2
- HLA-F-AS1 | n.1506C>T | RNA (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- HNRNPCP2 | n.316G>A | RNA (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.-39A>C | 5'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, varscan2
- IGLL5 | c.-101G>A | 5'UTR (SNP) | VAF 16/21 reads (76%) | called by muse, mutect2, varscan2
- IL31 | c.*188A>G | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- IZUMO3 | c.*7C>G | 3'UTR (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2, varscan2
- KCNE2 | c.*32C>T | 3'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as rs72550217; called by muse, mutect2, varscan2
- KIF13A | c.146+36024T>G | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- LINC00452 | n.969G>A | RNA (SNP) | VAF 42/143 reads (29%) | catalogued as rs777697898; called by muse, mutect2, varscan2
- LMTK2 | c.-237C>T | 5'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs1050471725; called by muse, mutect2, varscan2
- LPP | c.*4907G>C | 3'UTR (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- MCM2 | c.-34T>C | 5'UTR (SNP) | VAF 82/142 reads (58%) | called by muse, mutect2, varscan2
- MDFIC | c.94+381C>G | Intron (SNP) | VAF 41/355 reads (12%) | called by muse, mutect2, varscan2
- MGLL | c.*1608G>T | 3'UTR (SNP) | VAF 47/85 reads (55%) | catalogued as rs1047040722; called by muse, mutect2, varscan2
- MTHFD2 | c.*591del | 3'UTR (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- MTMR2 | c.*1703C>T | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- NECTIN4 | c.*579C>A | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- NPHP1 | c.1881+91del | Intron (DEL) | VAF 18/46 reads (39%) | called by mutect2, varscan2
- PARP12 | c.1781-563C>T | Intron (SNP) | VAF 41/309 reads (13%) | called by muse, mutect2, varscan2
- PARP14 | c.*1815C>T | 3'UTR (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- PDXK | c.143-3290G>C | Intron (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- PDXK | c.143-3029G>A | Intron (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- PEG10 | c.*4749C>A | 3'UTR (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- POFUT1 | c.542+288C>T | Intron (SNP) | VAF 25/168 reads (15%) | catalogued as rs767589486; called by muse, mutect2, varscan2
- PPP1R12B | c.*2477G>A | 3'UTR (SNP) | VAF 16/89 reads (18%) | catalogued as rs745832965; called by muse, mutect2, varscan2
- PRPS1 | c.-109G>C | 5'UTR (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- PRPSAP1 | chr17:76354125 T>C | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- PRSS23 | c.*1899T>A | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- PTH1R | c.*96G>A | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.5167-44G>A | Intron (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- QKI | c.*7653G>A | 3'UTR (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- RAB27B | c.*1576_*1577insA | 3'UTR (INS) | VAF 28/70 reads (40%) | called by mutect2, varscan2
- RAB6D | c.*1301G>A | 3'UTR (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.*1719T>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- RBM24 | c.*1217T>C | 3'UTR (SNP) | VAF 6/128 reads (5%) | catalogued as rs992274544; called by muse, mutect2
- RNU7-115P | chr17:64824861 C>A | 3'Flank (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- SERPINI2 | c.*163T>G | 3'UTR (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- SLC25A37 | c.*2650T>G | 3'UTR (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99264002; called by muse, mutect2, varscan2
- SLC35D1 | c.*2676G>T | 3'UTR (SNP) | VAF 22/49 reads (45%) | catalogued as rs1184498494, COSV52431788; called by muse, mutect2, varscan2
- SLITRK4 | chrX:143628001 C>A | 3'Flank (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- SP1 | c.*4299C>T | 3'UTR (SNP) | VAF 8/29 reads (28%) | catalogued as rs1372591316; called by muse, mutect2, varscan2
- SPAG9 | c.*503T>C | 3'UTR (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+492G>C | Intron (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- SST | c.-14T>A | 5'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- STPG2 | c.*2657A>T | 3'UTR (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- SYBU | c.25-718G>A | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- TADA3 | c.*111C>T | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- TAF13 | c.*324T>C | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2
- TASOR | c.4301-87G>A | Intron (SNP) | VAF 223/365 reads (61%) | catalogued as rs559971311; called by muse, mutect2, varscan2
- TENT5A | c.*3466A>T | 3'UTR (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- TJP1 | c.-47G>T | 5'UTR (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- TMEM151B | c.*2577C>T | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- TMEM41B | c.*54-825A>G | Intron (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- TMEM95 | c.*444C>T | 3'UTR (SNP) | VAF 14/130 reads (11%) | catalogued as rs1239997859; called by muse, mutect2, varscan2
- TPD52 | c.-19G>A | 5'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs1179860702; called by muse, mutect2, varscan2
- TRERF1 | c.*177T>A | 3'UTR (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- TREX2 | c.-667+141A>T | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- TYMP | c.1159+14G>A | Intron (SNP) | VAF 20/46 reads (43%) | catalogued as rs778577134; called by muse, varscan2
- UBE2A | c.*792G>A | 3'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as rs1318947420; called by muse, mutect2, varscan2
- UMAD1 | c.*923C>T | 3'UTR (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- XPO5 | c.3067-17dup | Intron (INS) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- ZBTB6 | c.*1248T>A | 3'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- ZNF239 | c.*122C>T | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.553+48T>C | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
